Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BM, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BM-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:
Right thigh sarcoma.

Specimens Submitted:
1: Right leg mass

DIAGNOSIS:

1. Skin and soft tissue, right leg, mass, excision:
Pleomorphic sarcoma, high grade, with myogenic differentiation. (see Note)

Size - 13.5 cm in greatest dimension.
Tumor involves the deep soft tissue and skeletal muscle.
Necrosis present. (60% of the tumor)
Resection margins are free of tumor.

Note: Immunohistochemical stains reveal that the tumor cells are focally positive for smooth muscle actin and desmin and negative for myogenin. This immunoprofile suggests a myogenic differentiation.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:
Result

Special Stain
RECUT
RECUT
RECUT
RECUT

Comment

Gross Description:

** Continued on next page **

OK IAD-0-3
Sarcoma, pleomorphic cell
(8802/3)
undifferentiated
(8805/3) Code to highest 8805/3
Sarcoma, pleomorphic cell 8802/3
Site: (R) thigh NOS C49.2
JD 11/22/13

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3

1. The specimen received fresh, labeled "right thigh" and consists of an oriented soft tissue resection, measuring 21x14x12.5 cm, with an attached skin ellipse, measuring 19x4 cm. Skin surface is unremarkable. The specimen is inked as followed: posterior=black, lateral=blue, medial=green, superior=orange, inferior=yellow, anterior=red. Serial sectioning reveals 13.5x11x10 cm, relatively well circumscribed, solid, tan mass within the skeletal muscle. The mass is 0.2 cm from posterior, lateral and medial margins, 0.9 cm from superior margin and > 1 cm from inferior and anterior margins. 60% of the mass is grossly necrotic. TPS is submitted, photo is taken and representative sections are submitted.

Summary of sections:

St-solid tm
Necr-necrosis
Tmsm-tumor with skeletal muscle
Tpm-posterior margin
Tam-anterior margin
Tsm-superior margin
Tim-inferior margin
Tlm-lateral margin
Tmm-medial margin
Skin-skin

Summary of Sections:

Part 1: Right leg mass

Block	Sect.	Site	PCs
1		necr	1
1		skin	1
1		sm	1
12		st	12
1		tam	1
1		tim	1
1		tlm	1
2		tmm	2
1		tpm	1
2		tsm	2

Intraoperative Consultation:

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

Page 3 of 3

** End of Report **

Source: NCI Genomic Data Commons file d9193f18-3460-4fb5-bcfc-b55e5480589b (TCGA-DX-A8BM.46CF2844-5279-4D05-B760-87D739F07006.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).